Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANQ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANQ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:

*Date - Date of Service:

Document Status:

Document Title:

Author:

Authenticated By:

Encounter info:

Contributor system:

* Final Report *

MICROSCOPIC EXAMINATION:

See final microscopic-diagnosis.

INTRAOPERATIVE GROSS CONSULTATION

Right testicle:

- mixed germ cell tumor

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right testicle". It consists of testicle with spermatic cord weighing 46 grams. The spermatic cord measures 8.5 cm in length x 1 cm in diameter and the testicle measures 5.5 x 3.5 x 3 cm. The tunica is freely mobile and does not appear involved by tumor. The testicle is bisected longitudinally to reveal a well-circumscribed tumor mass measuring 2.5 x 2 cm and has a variegated cut surface. The epididymis is identified and measures 3.2 in length x 0.4 cm in width, and does not appear to be grossly involved by tumor. Grossly, the normal testis is tan and strings freely. Representative sections are submitted in ten cassettes.

SECTIONS:

A1: spermatic cord margin
A2: mid spermatic cord
A3: distal spermatic cord (closest to testis)
A4: epididymis
A5-9: representative sections of tumor
A10: normal testis

Printed by:

Printed on:

Page 1 of 2
(Continued)

ICD-O-3
Carcinoma, embryonal
combined w/choriocarcinoma
path 9101/3
Mixed germ cell tumor 9085/3
Site @ Testis NOS C62.9
9/23/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

* Final Report *

Signature Line

CLINICAL INFORMATION:

Pre-op Dx: Right Testis Mass

SPECIMEN SOURCE:

A: "Right testicle"

COMMENT:

Immunohistochemical studies show the neoplastic cells are positive for pancytokeratin, CD30, PLAP, HCG and AFP, which supports the above diagnosis. The case was discussed with _____ on _____

DIAGNOSIS:

RIGHT RADICAL ORCHIECTOMY:

RIGHT TESTICLE:

INTRAOPERATIVE GROSS DIAGNOSIS:

- MIXED GERM CELL TUMOR

FINAL DIAGNOSIS:

- MIXED GERM CELL TUMOR WITH PREDOMINANT EMBRYONAL CARCINOMA, CHORIOCARCINOMA AND FOCAL YOLK SAC TUMOR (SEE COMMENT) 10%
- TUMOR IS CONFINED TO TESTICLE AND DOES NOT INVOLVE THE TUNICA ALBUGINEA, EPIDIDYMIS, OR SPERMATIC CORD
- SPERMATIC CORD MARGIN, NEGATIVE
- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- INTRATUBULAR GERM CELL NEOPLASIA PRESENT
- NO TERATOMA COMPONENTS IDENTIFIED

PATHOLOGIC TNM STAGE: pT1NXMX

Signature Line

Electronically signed by
Verified:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

*PW TSS dx discrepancy from,
TCGA tumor is: Embryonal carcinoma 90%,
Yolk Sac 10%*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Predominant Embryonal Carcinoma Choriocarcinoma & Focal Yolk Sac tumor	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 90%, Yolk Sac Tumor 10%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file f7315eb0-d5d9-4fc3-93b4-088ef83ed355 (TCGA-XE-AANQ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).